Gene-level copy-number profile of tumor specimen C3N-03070-02 from CPTAC case C3N-03070, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.0 years (24,111 days).
Specimen C3N-03070-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 75e5733f-7299-4f44-963f-05400f0e3497.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03070-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/bd5e20c5-d423-4944-bcc3-4566b7450dce

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 5,565; copy number 3: 11,325; copy number 4: 33,833; copy number 5: 7,062; copy number 6: 501; copy number 26: 4; copy number 28: 2; copy number 29: 2; copy number 32: 1; copy number 33: 1; copy number 35: 2; copy number 36: 4; copy number 37: 11; copy number 40: 4; copy number 42: 1; copy number 45: 3; copy number 47: 4; copy number 58: 3; copy number 59: 1; copy number 70: 4; copy number 71: 5; copy number 73: 5; copy number 78: 15; copy number 146: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 81 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:46,970,504–46,972,155, 1 gene, copy number 32: AC079906.1.
- chr12:47,484,689–47,593,440, 2 genes, copy number 28: AC003686.1, AC004486.1.
- chr12:47,706,083–47,742,294, 4 genes, copy number 26 (within-gene range 3–26): AC004241.1, ENDOU, AC004241.5, AC004241.2.
- chr12:48,105,139–48,146,404, 2 genes, copy number 29 (within-gene range 3–29): PFKM, MIR6505.
- chr12:54,230,942–54,351,846, 11 genes, copy number 37: CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P.
- chr12:57,591,174–57,619,638, 4 genes, copy number 47 (within-gene range 3–47): PIP4K2C, DTX3, ARHGEF25, AC025165.1.
- chr12:57,674,665–58,105,935, 31 genes, copy number 45–146: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:58,394,596–58,395,138, 1 gene, copy number 73: AC025578.1.
- chr12:76,315,751–76,316,048, 1 gene, copy number 36: RN7SKP172.
- chr12:109,347,903–109,536,705, 5 genes, copy number 42–70: MYO1H, LINC01486, AC007570.1, KCTD10, UBE3B.
- chr12:110,846,769–110,959,093, 4 genes, copy number 33–58: CCDC63, MYL2, LINC01405, AC002351.1.
- chr12:123,363,868–123,533,719, 7 genes, copy number 36–40 (within-gene range 3–40): SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1.
- chr12:131,801,315–131,945,896, 8 genes, copy number 35–71: RNA5SP378, MMP17, AC131009.2, ULK1, AC131009.4, AC131009.1, PUS1, AC131009.3.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
